Somatic mutation profile of tumor specimen TCGA-E1-A7YI-01A (aliquot TCGA-E1-A7YI-01A-11D-A34A-08) from TCGA case TCGA-E1-A7YI, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 33.5 years (12,229 days).
Specimen TCGA-E1-A7YI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1755b50b-c524-4cec-bfb5-a2ac311ebffc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YI-10A (Blood Derived Normal), aliquot TCGA-E1-A7YI-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/221bd73f-9ffb-4612-a072-1e3ec39b3b06

The open-access MAF lists 40 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/91 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTPN11 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs397507541, CM041072, COSV61005566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 37/73 reads (51%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARMC3 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.018); catalogued as rs1329347399, COSV53062701; called by muse, mutect2, varscan2
- ATG9B | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV100939885; called by muse, varscan2
- ATRX | c.4258A>T p.K1420* | Nonsense Mutation (SNP) | VAF 82/159 reads (52%) | catalogued as COSV100970204; called by muse, mutect2, varscan2
- CFAP54 | c.6250A>T p.R2084W | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100733004; called by muse, mutect2, varscan2
- CHD3 | c.5854C>T p.Q1952* (on ENST00000330494 / NM_001005273.3; = p.Q1918* on NM_005852.4) | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100177163; called by muse, mutect2, varscan2
- CYP11A1 | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139449608; called by muse, mutect2, varscan2
- DMXL2 | c.8077C>G p.L2693V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV99196061; called by muse, mutect2, varscan2
- DNAH5 | c.10115A>G p.D3372G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99446043; called by muse, mutect2
- EEPD1 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99631858; called by muse, mutect2, varscan2
- FCGBP | c.12526G>A p.G4176R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs556429522; called by muse, mutect2, varscan2
- FIP1L1 | c.1175-2A>C p.X392_splice | Splice Site (SNP) | VAF 1254/1342 reads (93%) | catalogued as COSV100184257; called by muse, mutect2, varscan2
- GLS | c.1488G>T p.M496I | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV100289804; called by muse, mutect2, varscan2
- KRT13 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as rs762655823, COSV55840513; called by muse, mutect2, varscan2
- MCU | c.730G>C p.A244P | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100849101; called by muse, mutect2, varscan2
- MRC1 | c.1659T>A p.S553R | Missense Mutation (SNP) | VAF 111/327 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99519315; called by muse, mutect2, varscan2
- NEBL | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV101008896; called by muse, mutect2, varscan2
- NLRP5 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs746597574, COSV101174046, COSV66761996; called by muse, mutect2, varscan2
- OPN1MW | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs782614830, COSV100884390; called by mutect2, varscan2
- OR8B2 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.861); catalogued as rs762460380, COSV100899343; called by muse, mutect2, varscan2
- PCDHA1 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs144781571, COSV65377125; called by muse, mutect2, varscan2
- REM1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as rs780128939, COSV52428487, COSV52430435; called by muse, mutect2, varscan2
- SHMT1 | c.1082T>C p.V361A | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as COSV100363479; called by muse, mutect2, varscan2
- SIK2 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs760355004, COSV100515997; called by muse, mutect2, varscan2
- SPTBN5 | c.3358_3359del p.S1120Cfs*184 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs906419969; called by pindel, varscan2
- SUPT20H | c.298G>A p.E100K (on ENST00000350612 / NM_001014286.3; = p.E101K on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779924914, COSV62246692; called by muse, mutect2, varscan2
- TREM2 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100632524; called by muse, mutect2, varscan2
- TYK2 | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99314389; called by muse, mutect2, varscan2
- UGT2B4 | c.782A>T p.Y261F | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100522249; called by muse, mutect2, varscan2
- ZC3H12C | c.2245G>A p.D749N | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV99584675; called by muse, mutect2, varscan2
- MCUB | c.269del p.L90Cfs*30 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | called by mutect2, pindel, varscan2
- COL11A1 | c.4458G>A p.G1486= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as rs773023575, COSV100615425; called by muse, mutect2, varscan2
- ENPP5 | c.144G>A p.T48= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs771162160, COSV100040330; called by muse, mutect2, varscan2
- GUCY1A1 | c.612C>T p.Y204= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV99637286, COSV99637752; called by muse, mutect2
- PDHA2 | c.495C>T p.V165= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as COSV54782731, COSV99757094; called by muse, mutect2, varscan2
- SLC18A2 | c.510T>C p.F170= | Silent (SNP) | VAF 46/140 reads (33%) | catalogued as COSV100041404; called by muse, mutect2, varscan2
- TREM2 | c.135G>A p.G45= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV58294402; called by muse, mutect2, varscan2
- NXF5 | n.1314T>C | RNA (SNP) | VAF 39/120 reads (33%) | catalogued as COSV99534143; called by muse, mutect2, varscan2
